TCGA case TCGA-12-0703 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0a85c7b4-f07d-4727-b9d2-7b14c52edabb

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 620 days (1.7 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 46.9 years (17,125 days); Year of diagnosis: 1996; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Monoclonal Antibody 81C6; Treatment intent type: Adjuvant; Days to treatment start: 13 days; Days to treatment end: 125 days; Treatment dose: 20 mg.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Days to treatment start: 13 days; Days to treatment end: 125 days; Treatment dose: 120 mCi; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 215 days; Days to treatment end: 302 days; Number of cycles: 3; Treatment dose: 125 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine; Initial disease status: Progressive Disease; Days to treatment start: 322 days; Days to treatment end: 530 days (1.5 years); Number of cycles: 5; Treatment dose: 100 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 322 days; Days to treatment end: 530 days (1.5 years); Number of cycles: 5; Treatment dose: 1 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 6,300 cGy; Number of fractions: 35; Treatment anatomic sites: Primary Tumor Field.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 47.5 years (17,333 days); Days to diagnosis: 208 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (4 entries)
- Day 208 (post initial treatment): Progression or recurrence: Yes; Days to progression: 208 days.
- Days to follow up: 551 days (1.5 years); Disease response: With Tumor.
- Days to follow up: 620 days (1.7 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-0703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.3; Shortest dimension: 0.1.
  Slide TCGA-12-0703-01A-01-BS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent monocyte infiltration: 50; Percent neutrophil infiltration: 50.
  Slide TCGA-12-0703-01A-02-BS2: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0; Percent neutrophil infiltration: 100.
- Sample TCGA-12-0703-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-0703-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: CPT-11.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: MAb I-131.
- Drug treatment 4: Pharmaceutical therapy drug name: mu81c6.
- Drug treatment 5: Pharmaceutical therapy drug name: Topecan.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 620 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 620 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 208 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-12-0703-01): tumor purity 0.74, ploidy 2.04, whole-genome doublings 0 (call status: legacy_call).
